Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A1AJ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A1AJ-01A (Primary Tumor).

ICD-0-3

Carcinoma, infiltrating duct, NOS 8500/3

Site Code: breast, NOS C50.9

12/24/10 lw

Final Diagnosis

Breast, right, wide local excision: Infiltrating ductal carcinoma, Nottingham grade III (of III), forming a mass, 1.2 x 1.1 x 0.9 cm. (AJCC pT1c). Angiolymphatic invasion is not identified. The surgical margins are negative for tumor. The closest margin (inferior) is free by 0.3 cm.

Lymph nodes, right axillary sentinel, excision: Multiple (2) right axillary sentinel lymph nodes are negative for tumor. Blue dye is not identified in either of the right axillary sentinel lymph nodes. Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression [AJCCpTN(i)].

Lymph nodes, right axillary, excision: Multiple (6) right axillary lymph nodes are negative for tumor.

HER2/neu protein overexpression is negative, score of 0, according to the interpretation guidelines in the FDA-approved HercepTest.

Source: NCI Genomic Data Commons file 62bf290e-85b8-48c8-b86e-77051091f9c6 (TCGA-AR-A1AJ.0DEAC35F-8B73-4A9F-B7FA-2F501B736B0E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).